Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4K9, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4K9-01A (Primary Tumor).

[page 1 of 2]
Collected:	DOB:	Sex: M
Received:	Physician:	
Case type: Surgical Case	Accession:	

DIAGNOSIS

(A) TOTAL THYROIDECTOMY: PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Right lobe
Multi-focal: No
Size = 1.5 cm
Extrathyroidal extension: Present, extending into fibroadipose tissue
Lymphovascular invasion: Absent
Resection Margins: Negative
Background Thyroid: Adenomatous nodule
Lymph nodes:
No lymph nodes present

(B) PORTION OF LEFT SUPERIOR PARATHYROID: Parathyroid tissue identified.

ICD-0-3
carcinoma, papillary, thyroid 8220/3
Site: thyroid, NOS C73.9

fw
10/4/12

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY – A total thyroidectomy with right lobe (5.1 x 3.2 x 1.5 cm) and left lobe (4.8 x 2.0 x 1.0 cm). The overlying surface of the thyroid is smooth. In the anterolateral aspect of the right middle portion of the thyroid is a 1.5 cm firm well-circumscribed nodule with slight adjacent round satellite nodules abutting the primary. The remaining thyroid is unremarkable.

SECTION CODE: A1-A3, representative sections of unremarkable left lobes, inferior; A4, A5, isthmus and adjacent fibroadipose tissue and possible lymph nodes A6-A12, sections of right lobe from superior to inferior (A7-A10, nodule in right lobe).

(B) PORTION OF LEFT SUPERIOR PARATHYROID – A piece of tan-brown soft tissue (0.2 x 0.2 x 0.1 cm, weighing 4 mg). Submitted in toto for frozen in cassette B.
*FS/DX: PARATHYROID TISSUE.

CLINICAL HISTORY

Papillary carcinoma.

SNOMED CODES

T-B6000, M-80503, M-Y3420, "Some tests reported here may have been developed and performance characteristics determined by
. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

[page 2 of 2]
3:
sician.

Sex: M

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

Entire report and diagnosis completed by:

Page 2 of 2

Surgical Pathology Report
File under: Pathology

lw
10/4/12

Source: NCI Genomic Data Commons file 008a65c1-39fd-4beb-b2ce-194ea4200fb7 (TCGA-EL-A4K9.C0BC2B9A-EA85-41B7-86CE-942DF49DA6F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).